Somatic mutation profile of tumor specimen C3N-02996-02 (aliquot CPT0187820033) from CPTAC case C3N-02996, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 78.0 years (28,479 days).
Specimen C3N-02996-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dc6cc1-a35f-4cf7-aa16-68437cf65a00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02996-31 (Blood Derived Normal), aliquot CPT0187870002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee9cdc8f-a305-4c5f-8d6c-d9507017483c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DGKK | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 14/349 reads (4%) | catalogued as rs1455453343; called by muse, mutect2
- MAGEA8 | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs782177723; called by muse, mutect2
